Somatic mutation profile of tumor specimen TCGA-H9-7775-01A (aliquot TCGA-H9-7775-01A-11D-2114-08) from TCGA case TCGA-H9-7775, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.2 years (24,898 days).
Specimen TCGA-H9-7775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2d3ef20-7e58-4bfe-8638-101d7ebb99e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H9-7775-10A (Blood Derived Normal), aliquot TCGA-H9-7775-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51f08d8b-006b-48bd-8bcd-a1428f64785d

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs774214806, COSV51114809, COSV99264364; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APLP1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55704682; called by muse, mutect2, varscan2
- ATP6AP2 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65797964; called by muse, mutect2, varscan2
- CCR6 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs753546769, COSV59474416; called by muse, mutect2, varscan2
- CSMD1 | c.9286G>A p.V3096M (on ENST00000520002; = p.V3095M on NM_033225.6) | Missense Mutation (SNP) | VAF 100/154 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs752743898, COSV59342750; called by muse, mutect2, varscan2
- EBI3 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55690562; called by muse, mutect2, varscan2
- GPAM | c.1657G>T p.D553Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV62081571; called by muse, mutect2, varscan2
- GSK3B | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as rs201787969, COSV51775499; called by muse, mutect2, varscan2
- KCNK10 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56647511; called by muse, mutect2, varscan2
- LRFN4 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs1245295703, COSV58920623; called by muse, mutect2, varscan2
- MMP28 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775131064; called by muse, mutect2, varscan2
- PAPLN | c.1057C>T p.R353C (on ENST00000554301; = p.R326C on NM_173462.4) | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752415617, COSV53720005; called by muse, mutect2, varscan2
- RASGEF1A | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs144867552; called by muse, mutect2, varscan2
- SGSM3 | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs768650949, COSV50653243; called by muse, mutect2, varscan2
- STAT4 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61830746; called by muse, mutect2, varscan2
- TCTN2 | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.462); catalogued as COSV57633566; called by muse, mutect2, varscan2
- TRIM16 | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1567666350, COSV60887242; called by muse, mutect2, varscan2
- TSPEAR | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV59968119; called by muse, mutect2, varscan2
- ZZEF1 | c.8345A>G p.D2782G | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV67558518; called by muse, mutect2
- DMTF1 | c.152_162del p.H51Lfs*5 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- CPXM1 | c.1368C>T p.I456= | Silent (SNP) | VAF 82/184 reads (45%) | catalogued as rs753724473, COSV66045956; called by muse, mutect2, varscan2
- CRP | c.585C>T p.G195= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs750660593, COSV54813954; called by muse, mutect2, varscan2
- DSCAM | c.951C>A p.T317= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV68029873; called by muse, mutect2, varscan2
- EIF3I | c.201C>T p.V67= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV59084823; called by muse, mutect2
- EP400 | c.1743G>T p.P581= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs914598377, COSV100200192, COSV57776736; called by muse, mutect2
- FAT3 | c.10059C>T p.D3353= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs751403167, COSV53133205; called by muse, mutect2
- RNF216 | c.693T>G p.S231= (on ENST00000425013 / NM_207116.3; = p.S288= on NM_207111.4) | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV66291351; called by muse, mutect2, varscan2
- TRPV3 | c.615C>T p.N205= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs372599650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EI24P4 | n.933C>T | RNA (SNP) | VAF 37/273 reads (14%) | catalogued as rs752601163; called by muse, mutect2, varscan2
